FM case AD258 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/0035b612-8955-4da5-a35d-bced5b32cbec

Male, 65.2 years: Duct adenocarcinoma, NOS (ICD-O-3 8500/3) of the pancreas. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
